Somatic mutation profile of tumor specimen TCGA-29-2436-01A (aliquot TCGA-29-2436-01A-01D-1526-09) from TCGA case TCGA-29-2436, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 36.5 years (13,346 days).
Specimen TCGA-29-2436-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c161beb-6c35-447c-9107-8cd0805ec987.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-2436-10A (Blood Derived Normal), aliquot TCGA-29-2436-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23288f24-dd30-40c9-8fbb-3e039b672610

The open-access MAF lists 8 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 3, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KAT6B | c.4963G>C p.V1655L | Missense Mutation (SNP) | VAF 159/379 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1299711614, COSV54756380; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHG3 | c.2762G>A p.G921D (on ENST00000394691; = p.G977D on NM_001308147.2) | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.642); catalogued as COSV55981813, COSV55984757; called by muse, mutect2, varscan2
- SORCS3 | c.1136C>T p.T379I | Missense Mutation (SNP) | VAF 103/787 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.449); catalogued as COSV63829116; called by muse, mutect2, varscan2
- CDH26 | c.1698C>T p.S566= | Silent (SNP) | VAF 96/365 reads (26%) | catalogued as COSV54857259; called by muse, mutect2, varscan2
- GAD2 | c.480G>A p.L160= | Silent (SNP) | VAF 91/200 reads (46%) | catalogued as COSV52171018; called by muse, mutect2, varscan2
- PHF8 | c.3057C>T p.R1019= (on ENST00000357988 / NM_001184896.1; = p.R983= on NM_015107.3) | Silent (SNP) | VAF 48/138 reads (35%) | catalogued as COSV57689467; called by muse, mutect2, varscan2
- SLC6A1 | c.984G>A p.S328= | Silent (SNP) | VAF 69/212 reads (33%) | catalogued as rs748162040, COSV55113560; called by muse, mutect2, varscan2
- BIRC8 | n.1057C>T | RNA (SNP) | VAF 18/51 reads (35%) | catalogued as rs756944611, COSV70346390; called by muse, mutect2, varscan2
